Gene-level copy-number profile of tumor specimen ALCH-B3ZK-TTP1-A from ALCHEMIST case ALCH-B3ZK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.0 years (22,636 days).
Specimen ALCH-B3ZK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b835d838-e8f6-484a-bb3f-ca3fcfe3a264.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/959b1dec-a546-4780-b340-f99918543e3e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 18,278; copy number 2: 33,908; copy number 3: 6,382; copy number 4: 197; copy number 5: 1; copy number 6: 35; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,812,962–52,897,562, 8 genes: ITIH4, AC006254.1, ITIH4-AS1, MUSTN1, STIMATE-MUSTN1, STIMATE, MIR8064, AC099667.1.
- chr6:34,537,802–34,556,333, 1 gene: SPDEF.
- chr8:43,542,076–43,544,057, 1 gene: AC134698.2.
- chr8:140,591,684–140,593,201, 1 gene (within-gene range 0–1): AC067931.2.
- chr8:143,696,154–143,698,413, 1 gene (within-gene range 0–1): LINC02878.
- chr9:21,695,176–22,455,740, 18 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:34,610,486–34,681,981, 11 genes: RPP25L, DCTN3, ARID3C, SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1, AL162231.2.
- chr9:124,257,606–124,353,307, 3 genes (within-gene range 0–1): NEK6, AL162724.2, AL162724.1.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.
- chr15:20,835,372–20,866,314, 2 genes: POTEB2, RNU6-749P.
- chr15:21,080,812–21,081,447, 1 gene: BCAR1P2.
- chr15:21,293,653–21,325,241, 3 genes (within-gene range 0–6): AC068446.1, AC068446.2, RNU6-1235P.
- chr15:75,645,020–75,763,322, 11 genes (within-gene range 0–1): AC105020.5, SNX33, CSPG4, AC105020.4, AC105020.1, ODF3L1, DNM1P35, AC019294.2, PPIAP47, AC019294.3, MIR4313.
- chr15:77,525,540–77,820,900, 7 genes: AC046168.1, AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1.
- chr15:78,749,833–78,811,464, 3 genes (within-gene range 0–1): AC022748.3, AC022748.1, ADAMTS7.
- chr15:85,750,336–85,794,925, 5 genes: AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr17:38,450,394–38,452,444, 1 gene (within-gene range 0–2): AC244153.1.
- chr19:14,137,146–14,171,267, 1 gene (within-gene range 0–2): AC022098.1.
- chr22:20,033,139–20,033,220, 1 gene (within-gene range 0–2): MIR185.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:20,890,206–20,890,606, 1 gene, copy number 5: AC012414.5.
- chr15:21,017,800–21,020,851, 2 genes, copy number 14: IGHD1OR15-1B, FAM30C.
- chr15:21,328,380–21,946,641, 35 genes, copy number 6: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.

Autosomal genes at a single copy (total copy number 1): 15,450. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
